Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GZ-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F
Reported:
Submitting Physicians:
Pathologist:
Intrapathologist:
Performing Physician:

Service:

Received:

CLINICAL HISTORY:
HEPATOCELLULAR CARCINOMA, HISTORY OF SKIN CARCINOMA.

PREOPERATIVE DIAGNOSIS:
NA

SPECIMEN TYPE(S):
A: GALLBLADDER & CONTENTS
B: RIGHT LOBE OF LIVER

FINAL DIAGNOSIS:
A. GALLBLADDER AND CONTENT, CHOLECYSTECTOMY:
Chronic cholecystitis, mild.
B. LIVER, RIGHT LOBE, RESECTION:
Hepatocellular carcinoma, moderately differentiated.
See Key Pathological Findings.

KEY PATHOLOGICAL FINDINGS:

Specimen type:	Right lobectomy
Tumor configuration:	Nodular
Tumor size:	8 x 6 x 5.2 cm
Histologic type:	Hepatocellular carcinoma
Histologic grade:	Moderately differentiated
Tumor necrosis:	Approximately 10%
Extent of invasion:	Limited to the liver
Perineural invasion:	Not identified
Angiolymphatic invasion:	Present
Parenchymal margin:	Free of tumor
Bile duct margin:	Not applicable
Other margins:	Free of tumor
Venous (large vessel) invasion:	Absent
Additional pathologic findings:	Extensive intrahepatic cholestasis
Lymph nodes:	Not applicable
Pathologic stage:	T2 NX MX

I, _____, the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:
NA

GROSS DESCRIPTION:

A. Specimen is received in formalin labeled with the patient's name and designated, "gallbladder and contents" consists of a tubular gallbladder with a soft tan-pink surface, 8.1 cm in length, ranging from 1.1 to 2.6 cm in diameter. The gallbladder neck is clipped and the gallbladder mucosa is velvety green-yellow. The gallbladder contains

ICD-O-3
Carcinoma, hepatocellular
NOS 8170/3
Site: Liver C22.0
JW 4/28/14

[page 2 of 2]
viscous green bile and no stones. The gallbladder wall is uniformly 0.2 cm in thickness. Representative sections are submitted as follows:

- A1: Gallbladder neck, body and fundus.
- A2: Gallbladder black margin, tangential.

B. Specimen is received in formalin labeled with the patient's name and designated, "right lobe liver" is oriented with a stitch at the tumor surface adjacent to the portal vein and consists of a 15.5 x 15 x 7-cm portion of liver. The area designated by the stitch is inked black and the remainder of the surgical margin is inked blue. The liver capsule is intact and finely nodular. In the superior portion of the specimen extending to the superior capsule, but not through the capsule, is a tan-yellow, centrally necrotic 4 x 6 x 5.2-cm tumor mass. The tumor comes to the resection margin at the area indicated adjacent to the portal vein, but is grossly encapsulated. The tumor comes to within 0.3 cm at the closest in the remainder of the resection margin. The remainder of the liver parenchyma is non fibrotic, tan-red. No satellite nodules are identified. A portion of the specimen was submitted to the Tissue Procurement Laboratory. Representative sections are submitted as follows:

- B1, B2: Tumor nearest liver capsule.
- B3, B4: Tumor with adjacent normal parenchyma.
- B5: Perpendicular surgical margin adjacent to portal vein.
- B6, B7: Perpendicular surgical margin of resection.
- B8: Central hemorrhagic area of tumor.
- B9: Grossly normal liver.

Source: NCI Genomic Data Commons file e1532b63-d9c4-4c2d-878a-b7245b3888e8 (TCGA-2Y-A9GZ.C389FDD7-0981-46EB-B51A-1BF6FCEC047F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).